Somatic mutation profile of tumor specimen MP2PRT-PAUEJC-TMP1-A (aliquot MP2PRT-PAUEJC-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUEJC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,913 days).
Specimen MP2PRT-PAUEJC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 791349b7-4fae-46a3-97b8-43a4b4fbb56b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUEJC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUEJC-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84af9104-3dde-4dc5-a34f-45370b07428a

The open-access MAF lists 53 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Nonsense Mutation 4, 5'UTR 2, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APBA2 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 27/795 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV68794303; called by muse, mutect2
- C16orf46 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs1192988275; called by muse, mutect2, varscan2
- CPNE5 | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 47/553 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.075); catalogued as rs760503915; called by muse, mutect2
- FAM83H | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 26/898 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1554622948; called by muse, mutect2
- FPGT-TNNI3K | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 38/516 reads (7%) | catalogued as rs749528030, COSV100598574, COSV63049029; called by muse, mutect2
- HRH1 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 119/345 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs201939588, COSV67955770; called by muse, mutect2, varscan2
- NEBL | c.2944G>A p.V982I | Missense Mutation (SNP) | VAF 160/384 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.09); catalogued as rs867653069, COSV65805131; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 77/444 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA13 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 143/444 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.966); catalogued as rs1356283866, COSV56477666, COSV99170418; called by muse, mutect2, varscan2
- REXO1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 32/837 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1287533810; called by muse, mutect2
- SYT1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 98/274 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs1355252350; called by muse, mutect2, varscan2
- TFDP1 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 18/375 reads (5%) | catalogued as COSV64740367; called by muse, mutect2
- TRIM58 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 35/822 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV63569922, COSV63572031; called by muse, mutect2
- WDR17 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV54567879; called by muse, mutect2, varscan2
- ZNF91 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as rs1311485707; called by muse, mutect2
- ZXDA | c.445C>G p.P149A | Missense Mutation (SNP) | VAF 42/962 reads (4%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV62388290; called by muse, mutect2
- AP000812.4 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 36/282 reads (13%) | called by muse, mutect2, varscan2
- CPZ | c.605C>T p.S202F (on ENST00000360986 / NM_001014447.3; = p.S191F on NM_003652.3) | Missense Mutation (SNP) | VAF 27/822 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- DSP | c.7513G>A p.E2505K | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ECHDC2 | c.416G>C p.G139A | Missense Mutation (SNP) | VAF 15/411 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- FAR2 | c.1399C>T p.H467Y | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT12 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- IGHV5-51 | chr14:106578736 ACTGTGTGTCT>TAAG | Missense Mutation (DEL) | VAF 73/94 reads (78%) | called by pindel, varscan2*
- LAMB1 | c.2861G>A p.R954K | Missense Mutation (SNP) | VAF 11/262 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2
- MAML2 | c.2629C>G p.Q877E | Missense Mutation (SNP) | VAF 13/421 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- MUC16 | c.35768C>A p.S11923* | Nonsense Mutation (SNP) | VAF 104/311 reads (33%) | called by muse, mutect2, varscan2
- MYH13 | c.353A>C p.Y118S | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- PARP4 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.434); called by muse, mutect2
- PLEKHG7 | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2
- PTPRK | c.1211G>C p.R404T | Missense Mutation (SNP) | VAF 55/416 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- SLC18A1 | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 90/241 reads (37%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- SRPRA | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.349); called by muse, mutect2
- SSX5 | c.132G>C p.E44D (on ENST00000347757 / NM_175723.1; = p.E85D on NM_021015.4) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.088); called by muse, mutect2
- STAG2 | c.1723T>A p.L575I | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); called by muse, mutect2
- TNXB | c.8389G>C p.D2797H (on ENST00000647633; = p.D2550H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/465 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- UBA2 | c.460-1G>C p.X154_splice | Splice Site (SNP) | VAF 13/258 reads (5%) | called by muse, mutect2
- WNK4 | c.2498C>T p.S833F | Missense Mutation (SNP) | VAF 28/361 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.14); called by muse, mutect2
- ZNF518B | c.3033G>C p.M1011I | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2
- CBX2 | c.570G>T p.R190= | Silent (SNP) | VAF 18/594 reads (3%) | called by muse, mutect2
- CBX2 | c.870G>C p.L290= | Silent (SNP) | VAF 15/582 reads (3%) | catalogued as COSV53968759; called by muse, mutect2
- CCNYL1 | c.709C>T p.L237= (on ENST00000295414 / NM_001330218.2; = p.L167= on NM_152523.2) | Silent (SNP) | VAF 12/398 reads (3%) | called by muse, mutect2
- CPNE8 | c.1503G>A p.V501= | Silent (SNP) | VAF 26/195 reads (13%) | catalogued as COSV58841736; called by muse, mutect2, varscan2
- IRAG1 | c.1002C>G p.L334= | Silent (SNP) | VAF 18/628 reads (3%) | called by muse, mutect2
- PLCL1 | c.1545C>T p.L515= | Silent (SNP) | VAF 54/382 reads (14%) | called by muse, mutect2, varscan2
- RASSF10 | c.144G>A p.R48= | Silent (SNP) | VAF 23/730 reads (3%) | called by muse, mutect2
- TF | c.957C>T p.H319= | Silent (SNP) | VAF 137/350 reads (39%) | catalogued as rs565363550, COSV99396384; called by muse, mutect2, varscan2
- UBE2M | c.318C>T p.L106= | Silent (SNP) | VAF 18/280 reads (6%) | catalogued as rs747688215; called by muse, mutect2
- USH2A | c.3873T>A p.S1291= | Silent (SNP) | VAF 16/367 reads (4%) | called by muse, mutect2
- YTHDF1 | c.618C>T p.V206= | Silent (SNP) | VAF 60/513 reads (12%) | catalogued as rs143100976; called by muse, mutect2
- ZNF410 | c.720C>G p.L240= | Silent (SNP) | VAF 18/268 reads (7%) | catalogued as COSV57912553; called by muse, mutect2
- CEP44 | c.-169G>C | 5'UTR (SNP) | VAF 27/462 reads (6%) | called by muse, mutect2
- IGHV3-53 | chr14:106592675 ins CCTCTCCCCA | 3'Flank (INS) | VAF 17/31 reads (55%) | called by pindel, varscan2
- WASL | c.-123G>A | 5'UTR (SNP) | VAF 22/416 reads (5%) | catalogued as rs1314258066; called by muse, mutect2
